Surgical pathology report (de-identified scan), TCGA case TCGA-24-2035, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2035-01A (Primary Tumor).

[page 1 of 6]
DIAGNOSIS

- OVARY, LEFT, BILATERAL SALPINGO-OOPHORECTOMY
- POORLY-DIFFERENTIATED PAPILLARY SEROUS CARCINOMA
- OVARY, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- POORLY-DIFFERENTIATED PAPILLARY SEROUS
CARCINOMA INVOLVING SEROSAL SURFACES
- FALLOPIAN TUBE, RIGHT, BILATERAL SALPINGO-OOPHORECTOMY
- SEROSAL METASTATIC POORLY-DIFFERENTIATED
PAPILLARY SEROUS CARCINOMA
- OMENTUM, PARTIAL OMENTECTOMY
- METASTATIC PAPILLARY SEROUS ADENOCARCINOMA
- LARGE INTESTINE, SIGMOID, PARTIAL RESECTION
- SEROSAL INVOLVEMENT BY METASTATIC
POORLY-DIFFERENTIATED PAPILLARY SEROUS CARCINOMA
- METASTATIC CARCINOMA IDENTIFIED IN 3 OF 3
PERISIGMOIDAL LYMPH NODES (3/3)
- BILATERAL RESECTION MARGINS FREE OF TUMOR
- SOFT TISSUE, RIGHT UPPER QUADRANT, EXCISION
- METASTATIC POORLY-DIFFERENTIATED PAPILLARY SEROUS CARCINOMA
- SOFT TISSUE, GASTROCOLIC OMENTUM, EXCISION
- METASTATIC POORLY-DIFFERENTIATED PAPILLARY SEROUS CARCINOMA
- SOFT TISSUE, "STOMACH NODULES", EXCISION
- METASTATIC POORLY-DIFFERENTIATED PAPILLARY SEROUS CARCINOMA
- UTERUS, SEROSA, TOTAL ABDOMINAL HYSTERECTOMY
- METASTATIC POORLY-DIFFERENTIATED PAPILLARY SEROUS CARCINOMA
- UTERUS, MYOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- METASTATIC POORLY-DIFFERENTIATED PAPILLARY SEROUS CARCINOMA
- UTERUS, ENDOMETRIUM, TOTAL ABDOMINAL HYSTERECTOMY
- INACTIVE ENDOMETRIUM

[page 2 of 6]
DIAGNOSIS (continued)

UTERUS, CERVIX, TOTAL ABDOMINAL HYSTERECTOMY

- NO HISTOPATHOLOGIC ABNORMALITY

LARGE INTESTINE, "END-TO-END ANASTOMOSES", PARTIAL SIGMOIDECTOMY
- NO HISTOPATHOLOGIC ABNORMALITY

SPECIMEN(S) SUBMITTED

- Part 1: FS1-RIGHT ADNEXAL MASS
- Part 2: K1-RIGHT ADNEXAL MASS
- Part 3: OMENTUM
- Part 4: UTERUS, CERVIX, LSO
- Part 5: PORTIONS OF SIGMOID
- Part 6: EEA
- Part 7: RIGHT UPPER QUAD TUMOR NODULES
- Part 8: GASTRO-COLIC OMENTUM
- Part 9: STOMACH NODULES

HISTORY

The patient is a [REDACTED] with a pelvic mass and an elevated CA125. Operative procedure: Total abdominal hysterectomy, bilateral salpingo oophorectomy, partial sigmoid resection and debulking.

FROZEN

FS1: Adnexa, right, biopsy - "Poorly differentiated carcinoma," [REDACTED]

GROSS

The specimens are received in nine containers of formalin, each labelled with the patient's name. The first container is labeled "FS." It contains a single disc of yellow-white tissue measuring 2.0 x 1.5 x 0.2 cm. Wrapped in filter paper. [REDACTED]

The second container is labeled "uterus, cervix, left salpingo oophorectomy." It contains a hysterectomy specimen including uterus, cervix, left fallopian tube and ovary. The uterus and cervix measures 6.0 cm from superior to inferior, 3.5 cm from cornu to cornu, and 3.0 cm from anterior to posterior. The

[page 3 of 6]
GROSS (continued)

specimen weighs 43.0 grams. The serosal surface is grey-tan with focal fibrinous adhesions. The superior aspect of the fundal serosa contains a plaque of yellow-tan, fibronopurulent-appearing material measuring 2.0 x 1.5 cm. The attached portion of fallopian tube including fimbriated end measures 3.5 cm in length x an average of 0.2 to 0.3 cm in diameter. The left ovary measures 1.5 x 0.4 x 0.4 cm. The external surface is white-tan and cerebriform. The internal surface is smooth, white, and glistening. There is no significant parametrial soft tissue or vagina attached to the specimen. The cervix measures 2.5 cm in diameter and contains a central slit-like os measuring 1.1 cm in length. The ectocervical mucosa is white-tan and shiny. The uterus is opened along its lateral border to show an endometrial cavity measuring 2.2 x 1.6 cm. It is lined by red-yellow, atrophic-appearing mucosa. The endocervical canal measures 1.5 x 0.6 cm. It is lined by yellow-tan, furrowed mucosa. There are no grossly suspicious areas noted. Sections of the cervix are unremarkable. Sections of the anterior myometrium show a serosal based firm white plaque extending from the superior fundus downward measuring 2.3 x 0.3 x 0.6 cm. It is grossly suspicious for tumor and appears to invade the anterior myometrium to a depth of 0.2 cm. Sections of the fallopian tube show a firm white internal surface suspicious for involvement by tumor. Labeled CX1 - anterior cervix; CX2 - posterior cervix; EM1 and EM2 - anterior endometrium with serosal based tumor; EM3 - posterior endometrium; LO - left ovary; LT - left tube.

The third container is labeled "right adnexa, X." It contains a previously bivalved ovary and a portion of fallopian tube including fimbriated end. The ovary measures 3.0 x 1.1 x 1.1 cm. The cut surface is smooth, white, and glistening, grossly consistent with involvement by tumor. Nodules of tumor are also identified grossly on the serosal surface of the soft tissue adjacent to the fallopian tube. The largest implant measures 0.6 x 0.4 x 0.2 cm. The portion of attached fallopian tube including fimbriated end measures 4.0 cm in length x 0.5 cm in diameter. Serial sections of the ovary show no grossly normal ovarian parenchyma. Serial sections of the fallopian tube are grossly unremarkable. Labeled: RO1 and RO2 - right ovary; RT - right tube; RP - tumor on serosal surface of parametrial soft tissue. Jar 1.

The fourth container is labeled "omentum." It contains a firm yellow-white omental cake measuring 17.0 x 17.0 x 4.5 cm. A second fragment measuring 5.5 x 3.5 x 2.5 cm is also present. Sections show firm white tumor that is vaguely lobular and

[page 4 of 6]
Name: 1

Surg. Path. No.:

GROSS (continued)

contains no gross evidence of necrosis.

The fifth container is labeled "portion of sigmoid." It contains an unoriented and tortuous portion of large intestine measuring 31.0 cm in length. Both margins are stapled. The specimen has been previously opened to show a pink-tan, furrowed mucosa. The wall is thickened, firm, and white measuring up to 2.5 cm. in thickness for a distance of 26 cm. The tumor does not grossly ulcerate through the mucosal surface however. The stapled margins are grossly uninvolved by tumor. Serial sections show extensive soft tissue involvement by tumor scattered, tumor nodules which may represent completely effaced lymph nodes are also identified. Labeled A1 and A2 - tumor involving wall of large intestine; A3 - soft tissue tumor; A4 - lymph nodes; A5 - bilateral staple margins.

The sixth container is labeled "end-to-end anastomosis." It contains two grossly unremarkable mucosal donuts ranging from 1.5 to 2.1 cm in diameter. Multiple staples are present.

The seventh container is labeled "right upper quadrant tumor nodules." It contains three fragments of firm white-tan tissue and yellow lobular adipose tissue measuring 7.0 x 5.5 x 2.5 cm. Sections show firm, white irregularly shaped islands of tumor surrounded by yellow lobular fat. There are no discrete lymph nodes identified.

The eighth container is labeled "gastrocolic omentum." It contains a single fragment of tissue measuring 4.0 x 3.5 x 2.0 cm. Sections show multiple ovoid to slightly irregular areas of firm white tumor which may represent effaced lymph nodes.

The ninth container is labeled "stomach nodules." It contains multiple fragments of yellow-tan adipose tissue embedded with firm white nodules of tumor ranging from 1.0 to 2.2 cm in maximum dimension.

COMMENT

Histologic sections of the specimen submitted show widespread, poorly-differentiated papillary serous carcinoma. The left ovary is identified within tissue adherent to the portion of sigmoid submitted. This ovary is largely replaced by tumor. Extensive

[page 5 of 6]
Name: "

Surg. Path. No.: 1

COMMENT (continued)

Surface involvement of the right ovary and right fallopian tube are noted as well. There is extensive omental involvement by tumor, as well as innumerable soft tissue tumor nodules in the specimen submitted as "right upper quadrant tumor", "gastrocolic omentum", and "stomach nodules."

The uterine serosa is extensively involved by metastatic papillary serous carcinoma, and tumor is identified in outer myometrial lymphatic spaces. The endometrium is inactive. The cervix shows no histologic abnormality. The left fallopian tube is not identified.

The portion of sigmoid submitted show encasement by metastatic papillary serous carcinoma. Three recognizable perisigmoidal lymph nodes show invasion by metastatic carcinoma. The resection margins, as well as the separately-submitted "end-to-end anastomoses" are free of tumor.

SYNOPTIC REPORTING FORM FOR MALIGNANT OVARIAN NEOPLASMS

1. A neoplasm is PRESENT.
2. The HISTOLOGIC DIAGNOSIS is:
Serous adenocarcinoma
3. The LOCATION(S) OF THE PRIMARY TUMOR(S) is/are:
Left ovary
4. The FIGO GRADE of the tumor is:
III (Tumor composed of greater than 50% solid cellular nests)
5. The NUCLEAR (BRODERS') GRADE of the tumor is:
G3 (Poorly-differentiated)
6. Tumor IS identified on the ovarian surface(s).
7. Tumor DOES invade the mesovarium.
8. Invasion of adjacent fallopian tube CANNOT BE EVALUATED.
12. Metastatic involvement of the omentum is PRESENT.
15. Metastatic involvement of the endometrium is ABSENT.
16. Regional lymph node metastases are PRESENT.
17. The total number of regional lymph nodes examined is 3.
18. The total number of metastatically-involved regional lymph nodes is 3.
Extranodal extension by tumor metastases is ABSENT
19. DETAILED STAGING INFORMATION:
THE STATUS OF DISTANT TUMOR SITES is classified as:
MX (Status cannot be assessed)

[page 6 of 6]
COMMENT (continued)

20. The FINAL AJCC/FIGO STAGE IS: Requires clinical correlation. The pathologic stage assigned here should be regarded as provisional, and may change after integration of clinical data not provided with this specimen.

{End of Report}

Source: NCI Genomic Data Commons file f1bce2da-0f5c-47da-83b4-d78a04a9ef03 (TCGA-24-2035.025D4B31-5832-451A-9F70-E0281F698AA6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).